CCDI case PBCJSV — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/3a9d8c6f-23f6-478a-a499-5e576b65486a

Demographics
Sex at birth: male.

Diagnoses (1)
1. Atypical teratoid/rhabdoid tumor: ICD-O-3 morphology code: 9508/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.1 years (395 days).

Biospecimens (3 samples)
- Sample 0DU7ZP: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DU806: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DU816: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
